Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A61S, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A61S-01A (Primary Tumor).

Gross Description: Tongue tissue up to 8 cm in size with gray dense-elastic tumor up to 5 cm in size, with ulceration.

Microscopic Description: Squamous carcinoma of the tongue, G-1, keratinizing type. Fatty tissue from the left side is with hemorrhages. In the fatty tissue from the right side there are six lymph nodes with normal morphological structure.

Diagnosis Details: Tumor Features: Indeterminate, Tumor Extent: Localized, NOS , Venous Invasion: Present, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: HEAD & NECK CHECKLIST

Squamous cell carcinoma, keratinizing of the oral cavity
5cm

Tumor size:

Laterality: Midline

ICD-O-3
Carcinoma, squamous cell,
keratinizing NOS 8071/3
Site: Tongue NOS C02.9
JW 4/12/13

Criteria	JW 4/2/13	Yes	No
Prior Tumor Site Discrepancy			✓
Case is Releasable			✓
Date	3/28/13		

Source: NCI Genomic Data Commons file 97ff658b-5928-4377-8e58-87af39b39918 (TCGA-F7-A61S.2FDEE481-0B8C-4553-8EA4-4FAB8AE66160.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).